Gene-level copy-number profile of tumor specimen C3N-01858-01 from CPTAC case C3N-01858, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 62.9 years (22,982 days).
Specimen C3N-01858-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54f2f029-ecb4-485d-b5c4-b0a328f08beb.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01858-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/a714e12a-6b50-45d1-81c7-1b28840afa30

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 20; copy number 2: 5,661; copy number 3: 82; copy number 4: 50,523; copy number 5: 27; copy number 6: 2,408; copy number 7: 92; copy number 8: 9; copy number 9: 1; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:159,186,835–159,712,435, 10 genes (within-gene range 0–2): MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13.
- chr3:36,968,191–36,993,131, 4 genes: RNU6ATAC4P, AC011816.2, PRADC1P1, EPM2AIP1.
- chr3:37,016,523–37,017,014, 1 gene (within-gene range 0–2): RPL29P11.
- chr9:19,895,800–23,438,700, 74 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:97,492,663–97,589,965, 1 gene, copy number 10 (within-gene range 4–10): ANKRD36B.
- chr18:5,081,171–5,098,780, 1 gene, copy number 9: LINC01892.

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
